Somatic mutation profile of tumor specimen MBCProject_3672_T1_WES (aliquot MBCProject_3672_T1_WES_1) from CMI case MBCProject_3672, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 48.2 years (17,616 days).
Specimen MBCProject_3672_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7a2847a-29ce-47f6-8e3f-d47e0622969b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3672_SALIVA (Saliva), aliquot MBCProject_3672_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/212620c9-2468-4d65-a80f-c1a393cd86fe

The open-access MAF lists 40 somatic variants for this specimen: 20 protein-altering or splice-affecting, 9 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 9, Intron 6, 3'UTR 2, Translation Start Site 1, 5'UTR 1, Nonsense Mutation 1, 3'Flank 1, Frame Shift Del 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.320A>T p.D107V | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786204858, CM142082, COSV64290655, COSV64294121; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCDC166 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs1554616834; called by muse, mutect2, varscan2
- SNRPD2 | c.300C>G p.F100L | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50003455; called by muse, mutect2, varscan2
- ADGRB1 | c.166T>C p.S56P | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- CDH1 | c.377dup p.P127Afs*41 | Frame Shift Ins (INS) | VAF 30/92 reads (33%) | called by mutect2, pindel, varscan2
- COL5A2 | c.3406C>T p.R1136* | Nonsense Mutation (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- CPAMD8 | c.4445C>T p.A1482V (on ENST00000651564; = p.A1435V on NM_015692.5) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- CR1L | c.-11_5delinsA | Translation Start Site (DEL) | VAF 71/307 reads (23%) | called by pindel, varscan2*
- DGKK | c.3406C>G p.P1136A | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- EXOC4 | c.1093G>C p.D365H | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- HERC1 | c.7463del p.N2488Ifs*11 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- NBR1 | c.710A>G p.Y237C | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLXNB3 | c.5485G>A p.D1829N | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHANK1 | c.6207G>T p.L2069F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SLC36A3 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC44A1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- SOX11 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, varscan2
- SUPT5H | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.047); called by muse, varscan2
- WASHC2A | c.1910C>A p.S637Y | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- XBP1 | c.401G>C p.R134T | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL6A5 | c.1074G>A p.A358= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs965535228, COSV55196460; called by muse, mutect2, varscan2
- DOCK3 | c.5187C>T p.N1729= | Silent (SNP) | VAF 44/143 reads (31%) | catalogued as rs767901544; called by muse, varscan2
- IGSF11 | c.885T>A p.S295= (on ENST00000393775 / NM_001015887.3; = p.S294= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/31 reads (45%) | called by muse, varscan2
- NUP62 | c.315C>G p.T105= | Silent (SNP) | VAF 148/484 reads (31%) | called by muse, mutect2, varscan2
- OR1B1 | c.117C>A p.T39= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV59172282; called by muse, mutect2
- PREX2 | c.2655C>T p.F885= | Silent (SNP) | VAF 25/110 reads (23%) | called by muse, varscan2
- SCYL1 | c.48C>T p.L16= | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2
- SEC14L4 | c.279C>T p.Y93= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs754750771, COSV55400397; called by muse, mutect2, varscan2
- SLC2A6 | c.618C>T p.I206= | Silent (SNP) | VAF 55/202 reads (27%) | called by muse, mutect2, varscan2
- ACBD5 | chr10:27195945 C>G | 3'Flank (SNP) | VAF 8/44 reads (18%) | catalogued as rs1475586677; called by muse, varscan2
- AL353804.7 | chrX:73845657 A>C | 5'Flank (SNP) | VAF 24/104 reads (23%) | called by muse, mutect2, varscan2
- BBS2 | c.1226-48T>C | Intron (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2
- CALY | c.246+161G>T | Intron (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- CD55 | c.1081+1172T>C | Intron (SNP) | VAF 8/118 reads (7%) | catalogued as rs1260729418; called by muse, mutect2
- LAMTOR1 | c.*46C>G | 3'UTR (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- LGALS3 | c.597+750A>G | Intron (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- R3HDM2 | c.*446A>G | 3'UTR (SNP) | VAF 7/45 reads (16%) | catalogued as rs1453353142; called by muse, mutect2, varscan2
- SH2D3C | c.516-5466C>T | Intron (SNP) | VAF 33/107 reads (31%) | catalogued as rs545137782; called by muse, mutect2, varscan2
- SLC5A6 | c.-368T>A | 5'UTR (SNP) | VAF 91/332 reads (27%) | called by muse, mutect2, varscan2
- TUBGCP2 | c.616+586A>G | Intron (SNP) | VAF 12/106 reads (11%) | called by muse, varscan2
